Somatic mutation profile of tumor specimen TCGA-CN-A63V-01A (aliquot TCGA-CN-A63V-01A-11D-A28R-08) from TCGA case TCGA-CN-A63V, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cheek mucosa; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 59.5 years (21,734 days).
Specimen TCGA-CN-A63V-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0ccdf086-18a4-414b-8e2f-aacce71eb3f8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CN-A63V-10A (Blood Derived Normal), aliquot TCGA-CN-A63V-10A-01D-A28U-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5cf56bab-66fe-43d4-a059-f068ec81e18b

The open-access MAF lists 91 somatic variants for this specimen: 73 protein-altering or splice-affecting, 16 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 64, Silent 16, Nonsense Mutation 4, Frame Shift Del 2, Splice Site 2, Intron 1, In Frame Del 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HRAS | c.34G>A p.G12S | Missense Mutation (SNP) | VAF 12/86 reads (14%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen benign (0.383); catalogued as rs104894229, CM053283, CM061797, COSV54236795, COSV54236828, COSV54237299; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- SMARCA4 | c.3404G>A p.R1135Q | Missense Mutation (SNP) | VAF 9/24 reads (38%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100758997, COSV60787834; called by muse, mutect2, varscan2
- ACSL6 | c.10C>T p.Q4* (on ENST00000379240; = p.Q29* on NM_015256.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 6/30 reads (20%) | catalogued as COSV99732654; called by muse, mutect2, varscan2
- ADAMTS2 | c.2036G>A p.R679H | Missense Mutation (SNP) | VAF 19/143 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.026); catalogued as rs144554943, COSV52381631; called by muse, mutect2
- AJUBA | c.1277G>A p.C426Y | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99400816; called by muse, mutect2, varscan2
- AKR7A3 | c.317G>A p.R106Q | Missense Mutation (SNP) | VAF 28/165 reads (17%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as rs781498992, COSV64389223; called by muse, mutect2, varscan2
- ASH1L | c.1897G>T p.V633L | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV100853118; called by muse, mutect2
- BCAS3 | c.735C>G p.N245K | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as COSV101175245; called by muse, mutect2, varscan2
- C20orf194 | c.1591-1G>A p.X531_splice | Splice Site (SNP) | VAF 17/96 reads (18%) | catalogued as COSV99330301; called by muse, mutect2, varscan2
- C5orf34 | c.691C>T p.H231Y | Missense Mutation (SNP) | VAF 16/154 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as rs1205123869, COSV100175337; called by muse, mutect2, varscan2
- CDK8 | c.584T>C p.V195A | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV67421306, COSV67421405; called by muse, mutect2, varscan2
- CGAS | c.1300T>C p.S434P | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.473); catalogued as COSV100943621; called by muse, mutect2, varscan2
- CSF1 | c.757C>T p.P253S | Missense Mutation (SNP) | VAF 28/115 reads (24%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.979); catalogued as rs887172482, COSV100294312; called by muse, mutect2, varscan2
- CSF1R | c.412G>A p.V138I | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT tolerated (0.27); PolyPhen benign (0.143); catalogued as rs755093010, COSV53833674; called by muse, mutect2, varscan2
- CSMD1 | c.1632C>G p.F544L (on ENST00000520002; = p.F543L on NM_033225.6) | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV100144077, COSV59283795; called by muse, mutect2, varscan2
- CTNNA2 | c.199G>A p.A67T | Missense Mutation (SNP) | VAF 5/60 reads (8%) | SIFT tolerated (0.05); PolyPhen benign (0.388); catalogued as COSV100781807; called by muse, mutect2
- CUEDC1 | c.886C>T p.P296S | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (0.8); PolyPhen benign (0.003); catalogued as rs1218984577, COSV100804665; called by muse, mutect2, varscan2
- CUX1 | c.4415G>A p.R1472H | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs782550484, COSV99470502; called by muse, mutect2
- DCC | c.329C>T p.P110L | Missense Mutation (SNP) | VAF 13/122 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100498271; called by muse, mutect2, varscan2
- DLC1 | c.1783C>T p.R595C (on ENST00000276297 / NM_001348081.2; = p.R158C on NM_006094.5) | Missense Mutation (SNP) | VAF 18/143 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.513); catalogued as rs749705851, COSV99361177; called by muse, mutect2, varscan2
- DNAH8 | c.2563C>T p.R855W | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs755566659, COSV59439776; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DNMT1 | c.1847C>T p.T616M | Missense Mutation (SNP) | VAF 115/276 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61583996; called by muse, mutect2, varscan2
- FAM189A2 | c.1292G>A p.R431Q | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs763475423, COSV57383623; called by muse, mutect2, varscan2
- FREM1 | c.2941G>C p.V981L | Missense Mutation (SNP) | VAF 21/112 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.844); catalogued as COSV101083830; called by muse, mutect2, varscan2
- GRAMD2B | c.565G>T p.A189S | Missense Mutation (SNP) | VAF 16/108 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0.011); catalogued as rs1161578936, COSV99586957; called by muse, mutect2, varscan2
- H3C10 | c.18G>T p.Q6H | Missense Mutation (SNP) | VAF 16/134 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.007); catalogued as COSV60797895; called by muse, mutect2, varscan2
- HDAC4 | c.2632G>T p.D878Y | Missense Mutation (SNP) | VAF 25/173 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100612698; called by muse, mutect2, varscan2
- HID1 | c.2078C>T p.P693L | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1331934260, COSV100172618, COSV60912108; called by muse, mutect2, varscan2
- IARS1 | c.3177G>C p.Q1059H | Missense Mutation (SNP) | VAF 17/103 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0.023); catalogued as COSV100986666, COSV100986672; called by muse, mutect2, varscan2
- IGHA2 | c.148G>T p.A50S | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT tolerated (0.41); PolyPhen benign (0.246); catalogued as rs113035575; called by muse, mutect2, varscan2
- KBTBD3 | c.1793A>C p.Q598P | Missense Mutation (SNP) | VAF 9/85 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.394); catalogued as COSV101595668; called by muse, mutect2
- KCNQ3 | c.557G>T p.G186V | Missense Mutation (SNP) | VAF 33/244 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101195616; called by muse, mutect2, varscan2
- LEPR | c.1261C>T p.R421C | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs1203802094, COSV60758975; called by muse, mutect2, varscan2
- LZTS1 | c.1513G>A p.E505K | Missense Mutation (SNP) | VAF 12/113 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.185); catalogued as COSV99742682; called by muse, mutect2, varscan2
- MROH6 | c.1715T>C p.V572A | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.288); catalogued as COSV101295793; called by muse, mutect2
- MUC16 | c.40102G>A p.V13368I | Missense Mutation (SNP) | VAF 33/84 reads (39%) | SIFT tolerated, low confidence (0.91); PolyPhen possibly damaging (0.737); catalogued as COSV101109605; called by muse, mutect2, varscan2
- MUC17 | c.1646G>A p.S549N | Missense Mutation (SNP) | VAF 217/785 reads (28%) | SIFT tolerated (0.24); PolyPhen benign (0.134); catalogued as COSV100071645, COSV60281675; called by muse, mutect2, varscan2
- MUC5B | c.11005G>A p.G3669S | Missense Mutation (SNP) | VAF 40/397 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.038); catalogued as rs763796582, COSV71591685; called by muse, mutect2, varscan2
- MYT1L | c.2917G>A p.A973T | Missense Mutation (SNP) | VAF 20/130 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs749215430, COSV67702315; called by muse, mutect2, varscan2
- NCOA4 | c.173G>A p.R58H | Missense Mutation (SNP) | VAF 27/174 reads (16%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.991); catalogued as rs781954653; called by muse, mutect2, varscan2
- NLGN3 | c.164G>A p.R55Q | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.603); catalogued as rs764624943, COSV62443378; called by muse, mutect2, varscan2
- OBI1 | c.2044C>G p.L682V | Missense Mutation (SNP) | VAF 28/130 reads (22%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.021); catalogued as COSV99932284; called by muse, mutect2, varscan2
- OR4A5 | c.710G>T p.C237F | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as rs752967464, COSV100156965; called by muse, mutect2, varscan2
- OR5W2 | c.604G>A p.V202I | Missense Mutation (SNP) | VAF 9/92 reads (10%) | SIFT tolerated (0.93); PolyPhen benign (0.006); catalogued as rs780817012, COSV60619142; called by muse, mutect2
- PAPPA2 | c.4948C>T p.Q1650* | Nonsense Mutation (SNP) | VAF 6/75 reads (8%) | catalogued as COSV100867592; called by muse, mutect2
- PCDH10 | c.403G>A p.A135T | Missense Mutation (SNP) | VAF 33/176 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99993003; called by muse, mutect2, varscan2
- PCLO | c.2627C>T p.P876L | Missense Mutation (SNP) | VAF 56/347 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as COSV100427550; called by muse, mutect2, varscan2
- POLRMT | c.1390C>T p.R464W | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.613); catalogued as rs775678643, COSV101646090; called by muse, mutect2, varscan2
- PPIG | c.986C>A p.S329Y | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99644171, COSV99644943; called by muse, mutect2, varscan2
- PPOX | c.614C>A p.A205E | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT tolerated (0.23); PolyPhen benign (0.057); catalogued as CM031719, COSV57086831, COSV99237149; called by muse, mutect2, varscan2
- PPP6R3 | c.404A>T p.K135I | Missense Mutation (SNP) | VAF 6/73 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV104377658, COSV99675610; called by muse, mutect2
- PRSS53 | c.539G>A p.R180H | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.996); catalogued as rs374267853; called by muse, mutect2, varscan2
- PTP4A2 | c.255A>T p.L85F | Missense Mutation (SNP) | VAF 14/94 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.814); catalogued as COSV100685589; called by muse, mutect2, varscan2
- RC3H1 | c.491G>A p.R164Q | Missense Mutation (SNP) | VAF 14/83 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51198657; called by muse, mutect2, varscan2
- SCAF4 | c.1411C>T p.R471* | Nonsense Mutation (SNP) | VAF 10/67 reads (15%) | catalogued as rs868454222, COSV54583616; called by muse, mutect2, varscan2
- SCAF4 | c.982C>T p.Q328* | Nonsense Mutation (SNP) | VAF 40/240 reads (17%) | catalogued as COSV99740906; called by muse, mutect2, varscan2
- SEC61A1 | c.980C>T p.T327M | Missense Mutation (SNP) | VAF 21/157 reads (13%) | SIFT tolerated (0.29); PolyPhen benign (0.018); catalogued as COSV99684693; called by muse, mutect2, varscan2
- SLAMF1 | c.106C>A p.L36I | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT tolerated (0.56); PolyPhen benign (0.01); catalogued as COSV52498206, COSV99348949; called by muse, mutect2
- SLFNL1 | c.814C>T p.R272C | Missense Mutation (SNP) | VAF 14/117 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.031); catalogued as rs759086428, COSV100262796; called by muse, mutect2, varscan2
- SLITRK5 | c.1301G>A p.G434E | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.908); catalogued as rs988507297, COSV100280310; called by muse, mutect2
- SPATA16 | c.337C>A p.P113T | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.91); catalogued as COSV100650911; called by muse, mutect2, varscan2
- TMEM132B | c.2787A>T p.K929N | Missense Mutation (SNP) | VAF 10/123 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.747); catalogued as COSV100168615; called by muse, mutect2
- TMEM200C | c.121G>T p.V41L | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101274788; called by muse, mutect2, varscan2
- TTN | c.11594A>G p.E3865G (on ENST00000591111; = p.E3819G on NM_003319.4) | Missense Mutation (SNP) | VAF 22/96 reads (23%) | catalogued as COSV100594883; called by muse, mutect2, varscan2
- VSTM1 | c.593C>T p.T198M | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.586); catalogued as rs773562512, COSV58074633; called by muse, mutect2
- WDR1 | c.1237G>A p.V413I (on ENST00000382452; = p.V273I on NM_005112.5) | Missense Mutation (SNP) | VAF 16/106 reads (15%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as rs768686576, COSV66723399; called by muse, mutect2, varscan2
- WDR19 | c.2483G>A p.R828H | Missense Mutation (SNP) | VAF 12/120 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs771137155, COSV56469396, COSV56470847; called by muse, mutect2, varscan2
- ZMAT4 | c.349+1G>A p.X117_splice | Splice Site (SNP) | VAF 21/252 reads (8%) | catalogued as COSV52709743; called by muse, mutect2
- ZNF233 | c.1937A>C p.K646T | Missense Mutation (SNP) | VAF 47/111 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1372897487, COSV100492099; called by muse, mutect2, varscan2
- ZNF282 | c.910C>T p.R304W | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.638); catalogued as rs1220675786, COSV100021413; called by muse, mutect2, varscan2
- AQP11 | c.34_36del p.Q12del | In Frame Del (DEL) | VAF 8/42 reads (19%) | called by mutect2, pindel, varscan2
- SFN | c.659_662del p.M220Sfs*7 | Frame Shift Del (DEL) | VAF 25/181 reads (14%) | called by mutect2, pindel, varscan2
- ZNF660 | c.336del p.K113Nfs*117 | Frame Shift Del (DEL) | VAF 17/119 reads (14%) | called by mutect2, pindel, varscan2
- DDX60L | c.3789C>T p.L1263= | Silent (SNP) | VAF 4/35 reads (11%) | catalogued as COSV99486955; called by muse, mutect2
- EPHX4 | c.1041C>T p.N347= | Silent (SNP) | VAF 8/42 reads (19%) | catalogued as COSV100952637; called by muse, mutect2, varscan2
- FXR1 | c.1599G>T p.G533= | Silent (SNP) | VAF 8/82 reads (10%) | catalogued as COSV99976118; called by muse, mutect2
- GABRB1 | c.183C>T p.V61= | Silent (SNP) | VAF 52/315 reads (17%) | catalogued as COSV99780231; called by muse, mutect2, varscan2
- GRIN2B | c.3945C>T p.A1315= | Silent (SNP) | VAF 25/154 reads (16%) | catalogued as rs200657400, COSV101662915; ClinVar: likely benign; called by muse, mutect2, varscan2
- GRM1 | c.174G>A p.P58= | Silent (SNP) | VAF 14/106 reads (13%) | catalogued as rs766972240, COSV99264126; called by muse, mutect2, varscan2
- KCNA2 | c.1248C>T p.F416= | Silent (SNP) | VAF 19/118 reads (16%) | catalogued as COSV100315834; called by muse, mutect2, varscan2
- LRRC17 | c.921C>T p.I307= | Silent (SNP) | VAF 14/137 reads (10%) | catalogued as rs775367068, COSV99978220; called by muse, mutect2, varscan2
- MROH7 | c.3921C>T p.R1307= | Silent (SNP) | VAF 5/44 reads (11%) | catalogued as COSV100988523; called by muse, mutect2, varscan2
- NBEAL2 | c.6339C>T p.L2113= | Silent (SNP) | VAF 3/27 reads (11%) | called by muse, mutect2
- SLC17A9 | c.1095G>A p.P365= | Silent (SNP) | VAF 51/242 reads (21%) | catalogued as rs756409472, COSV64848272; called by muse, mutect2, varscan2
- SOX5 | c.1740C>T p.D580= | Silent (SNP) | VAF 20/132 reads (15%) | catalogued as rs1376642001, COSV100506038; called by muse, mutect2, varscan2
- TECPR2 | c.1149G>T p.L383= | Silent (SNP) | VAF 8/150 reads (5%) | catalogued as COSV100849824; called by muse, mutect2
- TP73 | c.150C>T p.D50= | Silent (SNP) | VAF 23/168 reads (14%) | catalogued as rs755616910, COSV100600956; called by muse, mutect2, varscan2
- WSCD2 | c.918G>A p.A306= | Silent (SNP) | VAF 21/130 reads (16%) | catalogued as rs367674517; called by muse, mutect2, varscan2
- ZNF592 | c.3576G>A p.A1192= | Silent (SNP) | VAF 7/37 reads (19%) | catalogued as rs752142106, COSV100245686; called by muse, mutect2, varscan2
- TRAC | c.*133dup | 3'UTR (INS) | VAF 38/284 reads (13%) | catalogued as rs747854238; called by mutect2, varscan2
- TTN | c.34265-4877C>T | Intron (SNP) | VAF 39/309 reads (13%) | catalogued as rs777792441, COSV100594882; called by muse, mutect2, varscan2
